Somatic mutation profile of tumor specimen C3L-02970-03 (aliquot CPT0217880006) from CPTAC case C3L-02970, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.9 years (21,524 days).
Specimen C3L-02970-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa7a869a-f182-45ff-ade6-faf1702981c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02970-31 (Blood Derived Normal), aliquot CPT0219880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53d7c558-6d8d-4ff4-8e90-e570a8f958f6

The open-access MAF lists 101 somatic variants for this specimen: 66 protein-altering or splice-affecting, 23 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 23, Intron 6, Nonsense Mutation 3, RNA 3, 5'Flank 1, Splice Region 1, Frame Shift Ins 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 396/469 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFAP91 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201045322, COSV56338931; called by muse, mutect2
- CHRNA5 | c.639dup p.D214* | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | catalogued as rs1202847637; called by mutect2, varscan2
- CNTN4 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761504879, COSV61877512; called by muse, mutect2, varscan2
- COG3 | c.1756T>C p.S586P | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs1369273810; called by muse, mutect2, varscan2
- CSMD3 | c.1694C>T p.P565L (on ENST00000297405 / NM_001363185.1; = p.P461L on NM_052900.3) | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs770488162, COSV52246013; called by muse, mutect2, varscan2
- CSNK2A2 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs539754676; called by muse, mutect2, varscan2
- CTDSPL2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV99526671; called by muse, mutect2, varscan2
- DCN | c.748T>C p.L250= | Splice Region (SNP) | VAF 19/348 reads (5%) | catalogued as rs1464682428; called by muse, mutect2
- DRD2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1403144265, COSV60755303, COSV60759749; called by muse, mutect2, varscan2
- FGD5 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs545861931; called by muse, mutect2, varscan2
- GPAT3 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs758465966, COSV52357531; called by muse, mutect2, varscan2
- IRF8 | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 192/450 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.178); catalogued as COSV51898739; called by muse, mutect2, varscan2
- KCNQ5 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 157/350 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV59664704; called by muse, mutect2, varscan2
- KCNT1 | c.1441G>A p.V481I (on ENST00000488444; = p.V500I on NM_020822.3) | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs778483249, COSV53704801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAGI1 | c.3911G>A p.R1304Q | Missense Mutation (SNP) | VAF 129/418 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1320193593; called by muse, mutect2, varscan2
- MSGN1 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 173/403 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558427939, COSV55264026; called by muse, mutect2, varscan2
- MUC3A | c.8918C>T p.P2973L | Missense Mutation (SNP) | VAF 25/350 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.031); catalogued as rs577819188; called by muse, mutect2
- OBSCN | c.3441G>C p.E1147D | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV52793065; called by muse, mutect2, varscan2
- OR13C3 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs369932733; called by muse, mutect2, varscan2
- PCDHA4 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 243/591 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs376395074, COSV63543797; called by muse, mutect2, varscan2
- PCDHB10 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs1333580766, COSV53376430; called by muse, mutect2, varscan2
- PCDHGA6 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 257/577 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs767101939, COSV53918069; called by muse, mutect2, varscan2
- PHF20 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 114/320 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.349); catalogued as rs527952040; called by muse, mutect2, varscan2
- PTPRG | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 135/489 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1344548288; called by muse, mutect2, varscan2
- RIMS2 | c.3311G>A p.R1104Q (on ENST00000666250 / NM_001348490.2; = p.R912Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518581, COSV99211923; called by muse, mutect2, varscan2
- RNF165 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV53971428; called by muse, mutect2, varscan2
- ROBO2 | c.3442C>T p.Q1148* | Nonsense Mutation (SNP) | VAF 70/237 reads (30%) | catalogued as COSV59927153; called by muse, mutect2, varscan2
- ROCK2 | c.2824G>C p.E942Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV59965774; called by muse, mutect2, varscan2
- RP1 | c.5387C>T p.T1796M | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs764959789, COSV55113518; called by muse, mutect2, varscan2
- STX11 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 248/568 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.427); catalogued as rs865966109, COSV100845452; called by muse, mutect2, varscan2
- SVEP1 | c.3530C>A p.P1177H | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57041306; called by muse, mutect2
- TAFA1 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs765684057, COSV72037005; called by muse, mutect2, varscan2
- TSPEAR | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 242/594 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs868907838, COSV59951840, COSV59970899; called by muse, mutect2, varscan2
- ALK | c.670_673dup p.S225Tfs*2 | Nonsense Mutation (INS) | VAF 89/234 reads (38%) | called by mutect2, pindel, varscan2
- ASXL3 | c.820T>G p.S274A | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- ATXN7L3 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACYBP | c.279A>C p.L93F | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCT8L2 | c.250C>G p.H84D | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNTN6 | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRIP3 | c.150G>T p.R50S | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.355); called by muse, mutect2
- CTHRC1 | c.643G>T p.V215F | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- CUL7 | c.1763A>G p.D588G | Missense Mutation (SNP) | VAF 186/461 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC13 | c.4045G>C p.A1349P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH3 | c.3797T>A p.V1266D | Missense Mutation (SNP) | VAF 73/492 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM133A | c.328A>T p.S110C | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- FMN1 | c.2278G>A p.A760T (on ENST00000616417 / NM_001277313.2; = p.A537T on NM_001103184.4) | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- IKBIP | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LTF | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 160/574 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- MAST4 | c.4154C>G p.P1385R (on ENST00000403625 / NM_001164664.2; = p.P1196R on NM_015183.3) | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTTP | c.2065T>A p.Y689N | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MYO1A | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 155/428 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPIPB15 | c.1216A>C p.S406R | Missense Mutation (SNP) | VAF 183/1224 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, varscan2
- OR10T2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR2G6 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PCDHGA12 | c.362T>A p.V121E | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- PPP2R5D | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 159/340 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD51AP2 | c.3266C>T p.P1089L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- RBMY1A1 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | called by mutect2, varscan2
- SCAF8 | c.320A>T p.K107M | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOX30 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- TBXA2R | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 226/621 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLX1 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 220/274 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TUT1 | c.2167G>T p.A723S | Missense Mutation (SNP) | VAF 120/238 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZBTB39 | c.1071A>C p.Q357H | Missense Mutation (SNP) | VAF 168/341 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ZMYM5 | c.1320A>C p.E440D | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by mutect2, varscan2
- ANO1 | c.2613G>A p.P871= | Silent (SNP) | VAF 53/171 reads (31%) | catalogued as rs752920987, COSV62445948; called by muse, mutect2, varscan2
- C12orf50 | c.987G>A p.A329= | Silent (SNP) | VAF 95/286 reads (33%) | catalogued as rs762685869, COSV100072284, COSV53894688; called by muse, mutect2, varscan2
- C2CD2 | c.1839C>A p.V613= | Silent (SNP) | VAF 30/301 reads (10%) | called by muse, mutect2, varscan2
- CLEC7A | c.711A>T p.S237= (on ENST00000304084 / NM_197947.3; = p.S191= on NM_022570.5) | Silent (SNP) | VAF 43/122 reads (35%) | called by muse, mutect2, varscan2
- CTNNA2 | c.82T>C p.L28= | Silent (SNP) | VAF 121/270 reads (45%) | called by muse, mutect2, varscan2
- DAPK1 | c.3507G>A p.L1169= | Silent (SNP) | VAF 109/247 reads (44%) | catalogued as rs528813093; called by muse, mutect2, varscan2
- DNAH6 | c.1671T>C p.D557= | Silent (SNP) | VAF 78/186 reads (42%) | called by muse, mutect2, varscan2
- EEPD1 | c.1128C>T p.N376= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs749902092; called by muse, mutect2, varscan2
- FRAS1 | c.3030C>G p.L1010= | Silent (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- ITIH6 | c.99A>G p.T33= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs1274685041; called by muse, mutect2, varscan2
- KIAA0232 | c.1014C>T p.H338= | Silent (SNP) | VAF 98/221 reads (44%) | catalogued as rs776129435; called by muse, mutect2, varscan2
- LRP1 | c.4356C>T p.D1452= | Silent (SNP) | VAF 157/359 reads (44%) | catalogued as rs771290632, COSV54502876; called by muse, mutect2, varscan2
- NUDT19 | c.570C>T p.D190= | Silent (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
- OR2AK2 | c.618C>T p.I206= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV63560562; called by muse, mutect2, varscan2
- PCDHGA9 | c.594C>T p.R198= | Silent (SNP) | VAF 111/254 reads (44%) | catalogued as COSV53965010; called by muse, mutect2, varscan2
- PDLIM4 | c.19C>T p.L7= | Silent (SNP) | VAF 187/437 reads (43%) | called by muse, varscan2
- RBP3 | c.1203C>T p.P401= | Silent (SNP) | VAF 278/368 reads (76%) | catalogued as rs781987959; called by muse, varscan2
- SALL4 | c.916C>T p.L306= | Silent (SNP) | VAF 159/359 reads (44%) | called by muse, mutect2, varscan2
- TBX21 | c.750G>C p.A250= | Silent (SNP) | VAF 71/176 reads (40%) | called by muse, mutect2, varscan2
- TMTC1 | c.2499A>G p.Q833= (on ENST00000539277 / NM_001193451.2; = p.Q725= on NM_175861.3) | Silent (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- TRABD2B | c.1503C>T p.I501= | Silent (SNP) | VAF 35/249 reads (14%) | catalogued as rs563082206; called by muse, mutect2, varscan2
- TSPAN33 | c.207C>T p.I69= | Silent (SNP) | VAF 125/404 reads (31%) | catalogued as rs1261109873, COSV99179714; called by muse, mutect2, varscan2
- WFDC5 | c.588C>A p.V196= | Silent (SNP) | VAF 201/484 reads (42%) | called by muse, mutect2, varscan2
- CAMK2A | c.985-967G>A | Intron (SNP) | VAF 22/258 reads (9%) | catalogued as rs927515606, COSV62245172; called by muse, mutect2
- COL18A1-AS2 | chr21:45405193 A>C | 3'Flank (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- FAM183BP | n.784G>A | RNA (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- GUK1 | c.476-63G>A | Intron (SNP) | VAF 55/116 reads (47%) | catalogued as rs762391593, COSV57158188; called by muse, mutect2, varscan2
- HNF1B | c.1045+57C>T | Intron (SNP) | VAF 33/110 reads (30%) | catalogued as rs773960148; called by muse, mutect2, varscan2
- HNRNPL | c.881-1142_881-1141del | Intron (DEL) | VAF 73/205 reads (36%) | catalogued as rs777949263; called by mutect2, pindel, varscan2
- MKNK1 | c.100+316C>T | Intron (SNP) | VAF 89/207 reads (43%) | called by muse, mutect2, varscan2
- SFTA3 | n.784C>G | RNA (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- SLC13A4 | chr7:135728900 C>T | 5'Flank (SNP) | VAF 30/97 reads (31%) | catalogued as rs1260935193; called by muse, mutect2, varscan2
- SLC25A51P4 | n.876C>T | RNA (SNP) | VAF 36/87 reads (41%) | catalogued as rs1564896616; called by muse, mutect2, varscan2
- TSPAN18 | c.-10-2575A>C | Intron (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- ZNF594 | c.*362G>C | 3'UTR (SNP) | VAF 389/456 reads (85%) | called by muse, mutect2, varscan2
